Surgical pathology report (de-identified scan), TCGA case TCGA-AA-3684, project TCGA-COAD (Colon Adenocarcinoma), tissue source site Indivumed, specimen TCGA-AA-3684-01A (Primary Tumor).

Diagnosis:

Right-sided hemicolectomy preparation with locally advanced, poorly differentiated mucinous adenocarcinoma of the cecum (G3) with invasion of all parietal layers, penetration of the peritoneum, spreading to a gathered loop of small intestine, multiple regional lymph node metastases and carcinosis of the peritoneum or omentum (pT4 L1 V0 pN2 9/10 pM1 [REDACTED])

Source: NCI Genomic Data Commons file a49cc01b-4f80-4185-986e-97b8a293a2f7 (TCGA-AA-3684.2FF5DB80-95DB-4EB6-9B72-25C83C492653.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).